Somatic mutation profile of tumor specimen 0D9QL5 from CCDI case PBBIYG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.6 years (4,956 days).
Specimen 0D9QL5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 195e09cf-1141-4c46-baec-a6d35cf5089a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9QL6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4f37e1e-4141-440b-81b2-43646e7fbcda

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, 3'UTR 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRH1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 125/237 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs201947424, COSV67955106; called by muse, varscan2
- KBTBD13 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 109/390 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs1259207440; called by muse, varscan2
- MRGPRE | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 101/148 reads (68%) | SIFT tolerated (0.37); PolyPhen benign (0.209); catalogued as rs776083106; called by muse, varscan2
- PAM | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV57213509, COSV57220653; called by muse, varscan2
- SEC16A | c.4967G>A p.R1656Q | Missense Mutation (SNP) | VAF 136/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769766754; called by muse, varscan2
- ZNF469 | c.11548C>T p.R3850W (on ENST00000437464; = p.R3878W on NM_001367624.2) | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs754381335; called by muse, varscan2
- BEST1 | c.188A>C p.E63A | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, varscan2
- DGKI | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- ZNF680 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 208/456 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- HERC2 | c.2238C>A p.R746= | Silent (SNP) | VAF 297/457 reads (65%) | catalogued as COSV55306761; called by muse, varscan2
- IGFLR1 | c.168C>T p.F56= | Silent (SNP) | VAF 72/183 reads (39%) | called by muse, varscan2
- MUC5B | c.9015C>A p.T3005= | Silent (SNP) | VAF 166/488 reads (34%) | called by muse, varscan2
- NKX2-4 | c.945G>A p.L315= | Silent (SNP) | VAF 62/132 reads (47%) | called by muse, varscan2
- PACSIN2 | c.627G>A p.E209= | Silent (SNP) | VAF 101/363 reads (28%) | called by muse, varscan2
- PROS1 | c.1008C>T p.G336= | Silent (SNP) | VAF 80/216 reads (37%) | catalogued as rs141208672; called by muse, varscan2
- A2M | c.4409-25A>T | Intron (SNP) | VAF 104/214 reads (49%) | catalogued as rs764262820, COSV59389556; called by muse, varscan2
- PPL | c.-87G>A | 5'UTR (SNP) | VAF 18/32 reads (56%) | called by muse, varscan2
- TCERG1L | c.*53C>T | 3'UTR (SNP) | VAF 37/41 reads (90%) | catalogued as rs186029190, COSV100894528; called by muse, varscan2
